Somatic mutation profile of tumor specimen MP2PRT-PAWCCP-TMP1-A (aliquot MP2PRT-PAWCCP-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWCCP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,118 days).
Specimen MP2PRT-PAWCCP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caa87696-0db2-418e-8715-6914351b8141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCCP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCCP-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33f95262-eed9-40cf-9e08-785a754c2fa1

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 396/611 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs202114705; called by muse, mutect2, varscan2
- FAT1 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 154/520 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as rs773192852; called by muse, mutect2, varscan2
- INHA | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 185/536 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs528720477; called by muse, mutect2, varscan2
- KIAA1217 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 82/428 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs150149691; called by muse, mutect2, varscan2
- KIAA1549L | c.3298C>T p.R1100W (on ENST00000321505; = p.R1397W on NM_012194.3) | Missense Mutation (SNP) | VAF 143/469 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757475102, COSV55775832, COSV55777990; called by muse, mutect2, varscan2
- KIF2B | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.549); catalogued as COSV52129077; called by muse, mutect2, varscan2
- LAMA1 | c.6562C>T p.R2188C | Missense Mutation (SNP) | VAF 130/503 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202184749, COSV67544266; called by muse, mutect2, varscan2
- LRMDA | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100995431; called by muse, mutect2, varscan2
- NHSL2 | c.391C>T p.R131W (on ENST00000510661; = p.R497W on NM_001013627.2) | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1285588439; called by muse, mutect2, varscan2
- GRID2IP | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 219/816 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IGHV3-38 | c.341_342insGAGA p.Y116Qfs*? | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by muse*, mutect2
- ABCC4 | c.222C>T p.D74= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs539483537, COSV65315460; called by muse, mutect2, varscan2
- ARHGAP22 | c.1083C>T p.R361= | Silent (SNP) | VAF 203/1002 reads (20%) | catalogued as rs1436390419; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 128/786 reads (16%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- PCDH11Y | c.3981G>A p.P1327= | Silent (SNP) | VAF 151/179 reads (84%) | catalogued as COSV53084663; called by muse, mutect2, varscan2
- DOCK1 | c.1059-30G>A | Intron (SNP) | VAF 102/548 reads (19%) | catalogued as rs755894167, COSV54764885; called by muse, mutect2, varscan2
